Gene-level copy-number profile of tumor specimen RC-B667-TBP1-B from RC case RC-B667, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: T-cell large granular lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.6 years (12,255 days).
Specimen RC-B667-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e62f241-618a-4b64-8ad8-1ca6674d3203.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B667-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/ea5c8a74-8d64-40a8-a177-d81df582b341

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 48; copy number 2: 57,038; copy number 3: 1,104; copy number 4: 66.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–2): TRGV5P, TRGV5.
- chr7:142,641,746–142,802,748, 28 genes: TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr14:22,281,105–22,552,156, 76 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 48. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
